Gene-level copy-number profile of tumor specimen TCGA-N5-A4R8-01A from TCGA case TCGA-N5-A4R8, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IA; Age at diagnosis: 66.0 years (24,102 days).
Specimen TCGA-N5-A4R8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.20deb490-e4b2-4731-b15b-d0d1213790ba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N5-A4R8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/7d0eb772-693d-4e60-b841-766e70047269

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 11,089; copy number 2: 29,471; copy number 3: 17,599; copy number 4: 716; copy number 5: 596; copy number 6: 147; copy number 7: 98; copy number 8: 44; copy number 16: 14.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:71,794,232–71,837,012, 1 gene: NEGR1-IT1.
- chr2:14,530,941–14,531,223, 1 gene: Metazoa_SRP.
- chr3:55,610,603–55,659,382, 2 genes: AC025572.1, ERC2-IT1.
- chr3:116,645,902–117,027,039, 8 genes: BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr4:181,064,089–181,700,142, 6 genes (within-gene range 0–1): LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2, AC084741.1.
- chr11:40,444,371–40,513,269, 1 gene: AC090720.1.
- chr15:47,359,430–47,527,756, 3 genes: AC023905.1, AC009558.1, AC009558.2.
- chr16:78,872,739–79,229,453, 12 genes (within-gene range 0–2): AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2, AC092376.2, AC092376.3, AC092376.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 899 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–21,239,796, 596 genes, copy number 5 (broad region; genes not listed).
- chr19:29,775,504–31,787,255, 32 genes, copy number 8–16: AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P.
- chr19:34,172,504–36,418,644, 147 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr19:38,403,135–38,912,158, 26 genes, copy number 8: FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K, ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2, NFKBIB, CCER2.
- chr19:39,083,913–40,808,418, 98 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,676. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
